Gene-level copy-number profile of tumor specimen ALCH-AEO0-TTP1-A from ALCHEMIST case ALCH-AEO0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.2 years (24,178 days).
Specimen ALCH-AEO0-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b070a272-aef3-4760-bfc9-ff1fcd78654a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEO0-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/b8352a66-eb32-48e3-abb9-bcfc0b98ab19

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 22,201; copy number 2: 26,179; copy number 3: 7,343; copy number 4: 1,188; copy number 5: 400; copy number 6: 405; copy number 7: 244; copy number 8: 226; copy number 9: 129; copy number 10: 35; copy number 11: 17; copy number 12: 5; copy number 13: 11; copy number 17: 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr9:78,297,125–78,330,093, 1 gene: PSAT1.
- chr9:124,451,425–124,478,589, 1 gene: ADGRD2.
- chr10:133,262,420–133,276,868, 1 gene: ADAM8.
- chr16:56,351,886–56,353,524, 1 gene (within-gene range 0–1): AC009102.2.
- chr16:89,873,570–89,938,761, 6 genes: TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3.
- chr21:13,762,338–13,764,332, 1 gene: FEM1AP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,473 genes in 43 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:91,949,371–94,592,297, 71 genes, copy number 5 (broad region; genes not listed).
- chr2:36,837,698–41,157,555, 75 genes, copy number 5 (broad region; genes not listed).
- chr2:44,154,789–46,187,990, 35 genes, copy number 5: RNU6-566P, PDSS1P2, AC019129.2, PPM1B, AC013717.1, RPL12P19, SLC3A1, PREPL, CAMKMT, LINC01833, AC012354.9, AC012354.2, AC012354.7, AC012354.5, AC012354.8, AC012354.4, AC012354.3, AC012354.6, SIX3-AS1, SIX3, AC012354.1, KRTCAP2P1, SIX2, AC093702.1, LINC01121, AC093833.1, AC009236.2, AC009236.1, SRBD1, RN7SL414P, PRKCE, PRKCE-AS1, RPL26P15, AC017006.2, AC017006.1.
- chr2:47,924,181–48,598,513, 10 genes, copy number 5 (within-gene range 4–5): AC092650.1, PPIAP62, VN1R18P, RN7SKP224, FOXN2, RNU4-49P, AC093635.1, PPP1R21, RNU6-282P, STON1.
- chr2:55,547,292–56,181,652, 12 genes, copy number 5 (within-gene range 4–5): PPP4R3B, AC015982.1, AC015982.2, PNPT1, EFEMP1, RN7SKP208, AC011306.1, MIR217HG, MIR217, MIR216A, MIR216B, LINC01813.
- chr2:58,251,440–59,063,766, 4 genes, copy number 5: EIF3FP3, LINC01795, LINC01122, AC007238.1.
- chr5:58,198–4,866,311, 96 genes, copy number 6–8 (within-gene range 3–8) (broad region; genes not listed).
- chr5:6,839,460–9,045,940, 48 genes, copy number 5–8 (within-gene range 2–8): LINC02196, RN7SKP79, AC122710.1, RNA5SP176, AC025756.1, Metazoa_SRP, AC091951.2, AC091951.3, AC091951.1, AC027343.3, LINC02123, AC027343.1, AC027343.2, LINC02142, ADCY2, AC093305.1, C5orf49, MTRR, FASTKD3, AC025174.1, RNU1-76P, AC091941.1, AC091912.2, AC091912.1, AC091912.3, LINC02226, AC091965.1, AC091965.3, AC091965.4, MIR4458HG, AC091965.2, AC091965.5, MIR4458, AC091953.1, AC091953.3, AC091953.5, MTND6P2, MTCYBP37, AC091953.2, AC091953.6, AC091953.4, AC091932.4, AC091932.2, AC091932.1, AC091932.3, LINC02199, AC091895.1, AC021088.1.
- chr5:12,297,399–14,532,128, 14 genes, copy number 5: RNU6-679P, AC106771.1, LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1, RPS23P5, NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1.
- chr5:15,112,120–16,440,081, 14 genes, copy number 5–8 (within-gene range 4–8): LINC02149, MARK2P5, AC114964.2, AC114964.1, FBXL7, CTD-2350J17.1, MIR887, RNA5SP178, MARCHF11, MARCHF11-AS1, AC092335.1, NACAP6, LINC02150, AC020980.1.
- chr5:80,556,755–81,892,721, 21 genes, copy number 5: ANKRD34B, DBIP2, LINC01337, DHFR, AC008434.1, MTRNR2L2, MSH3, AC022493.2, AC022493.1, RASGRF2-AS1, RASGRF2, AC026427.2, AC026427.1, CKMT2-AS1, CKMT2, AC026436.1, ZCCHC9, ACOT12, SSBP2, AC026726.1, SEM1P1.
- chr8:51,015,021–51,321,118, 2 genes, copy number 5 (within-gene range 2–5): AC090919.1, AC012413.1.
- chr8:56,776,283–58,582,859, 27 genes, copy number 5: AC009597.2, RNU6-13P, BPNT2, RNA5SP266, LINC01606, AC025674.1, AC025674.2, LINC00588, RNU6-596P, AC068075.1, RPL30P10, AC090796.1, AC104051.1, AC104051.2, LINC01602, AC012103.1, FAM110B, AC104350.1, AC027698.1, RPL26P26, AC092819.1, AC092819.2, UBXN2B, AC009927.1, CYP7A1, PPIAP85, SDCBP.
- chr8:60,046,755–61,501,645, 19 genes, copy number 6 (within-gene range 4–6): AC021393.1, SLC2A13P1, CA8, LINC01301, PDCL3P1, RAB2A, AC068389.3, AC068389.1, AC068389.2, CHD7, AC113143.1, IFITM3P8, AC022182.1, NASPP1, AC022182.2, CLVS1, NPM1P6, AC023866.2, AC023866.1.
- chr8:63,586,000–64,862,370, 17 genes, copy number 6: AC018953.1, RN7SKP135, AC018953.2, LINC01414, AC069133.1, LINC01289, COX6CP8, MIR124-2HG, MIR124-2, AC090136.1, AC090136.2, AC090136.3, BHLHE22, CYP7B1, AC104232.2, AC104232.3, AC104232.1.
- chr8:70,051,651–72,118,393, 27 genes, copy number 5–8 (within-gene range 1–8): PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA, AC022858.1, EYA1, TRAPPC2P2, AC009446.1, AC104012.1, U8, MSC-AS1, MSC, RPS20P20.
- chr8:79,520,145–83,408,900, 77 genes, copy number 6–8 (broad region; genes not listed).
- chr8:84,162,118–85,617,512, 24 genes, copy number 5–10: TPM3P3, AC012400.1, RALYL, RNU6-1040P, PSMC2P2, AC009901.1, AC009901.2, ACTBP6, JCHAINP1, AC091175.1, LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1, CA3, CA3-AS1, CA2, AC084734.1, AC093331.1.
- chr8:86,707,547–87,615,219, 4 genes, copy number 7 (within-gene range 3–7): AC090572.3, AC090572.2, AC090572.1, CNBD1.
- chr8:91,542,924–93,974,776, 42 genes, copy number 7: AC103409.1, RN7SKP231, PRR13P7, MRPS16P1, RUNX1T1, AF181450.1, AC104339.1, AC022695.1, AC022695.2, AC022695.3, AC091096.1, AC104211.1, FLJ46284, AC104211.2, AC117834.2, AC117834.1, TRIQK, IRF5P1, MIR8084, C8orf87, LINC00535, AC016885.1, AC016885.3, AC016885.2, RNA5SP274, ZNF317P1, CIBAR1, AC120053.1, AC010834.3, RBM12B, AC010834.1, RBM12B-AS1, AC010834.2, TMEM67, AC084346.1, MYL12AP1, PDP1, MIR378D2HG, MIR378D2, PSMA2P2, RPL34P18, AC105081.1.
- chr8:95,204,456–96,611,790, 20 genes, copy number 5 (within-gene range 3–5): C8orf37-AS1, LINC01298, C8orf37, AC024995.1, AC083836.1, RNU6-690P, SRSF3P2, AC012339.1, GAPDHP30, AC007992.1, AP003465.2, GDF6, UQCRB, AP003465.1, MTERF3, PTDSS1, Y_RNA, AP003548.1, RNU6-1172P, SDC2.
- chr8:100,133,351–100,464,613, 11 genes, copy number 13: FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2.
- chr8:115,950,511–117,540,262, 19 genes, copy number 6–10: LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16.
- chr8:118,620,498–121,380,465, 37 genes, copy number 5–7 (within-gene range 4–7): SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1, MRPL13, MTBP, SNTB1, NCAPGP1, AC104958.1, AC104958.2, AC068413.1, AC011626.1, RPL35AP19.
- chr8:123,215,788–123,416,350, 12 genes, copy number 7–9 (within-gene range 2–9): MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2.
- chr8:123,851,987–124,728,473, 20 genes, copy number 8: FER1L6, AC090753.1, FER1L6-AS1, AC100871.2, FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65, TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1.
- chr8:124,823,702–125,091,819, 9 genes, copy number 7 (within-gene range 4–7): LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1.
- chr8:126,072,587–130,655,712, 60 genes, copy number 5–7: KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1.
- chr8:132,120,859–138,497,261, 63 genes, copy number 5–12 (broad region; genes not listed).
- chr8:139,460,062–141,432,454, 32 genes, copy number 5–11: AC087354.1, AC090093.1, KCNK9, TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3.
- chr11:68,870,664–70,436,584, 50 genes, copy number 5–6: LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr14:26,599,755–27,295,516, 1 gene, copy number 6 (within-gene range 3–6): AL110292.1.
- chr14:26,831,401–38,606,098, 188 genes, copy number 6–9 (within-gene range 3–10) (broad region; genes not listed).
- chr14:38,738,155–49,897,054, 121 genes, copy number 5–9 (broad region; genes not listed).
- chr20:64,255,695–64,327,972, 5 genes, copy number 6: PCMTD2, AL137028.2, CICP4, LINC00266-1, AL137028.1.
- chr21:13,609,858–13,724,274, 9 genes, copy number 8: POTED, RNU6-286P, MIR3118-1, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5, MIR8069-2.
- chr21:13,792,635–14,763,090, 24 genes, copy number 9–17 (within-gene range 2–17): FAM207CP, GXYLT1P2, CNN2P7, ZNF114P1, CYP4F29P, SNX18P13, ANKRD20A11P, RHOT1P2, RNU6-954P, NF1P3, PPP6R2P1, FRG2MP, AP001347.1, ANKRD20A18P, RNA5SP488, AP001347.2, LIPI, ERLEC1P1, RBM11, ABCC13, HSPA13, SAMSN1, SAMSN1-AS1, AF127936.1.
- chr21:16,718,998–17,660,384, 16 genes, copy number 8: RNU1-98P, AF130359.1, AF212831.1, NEK4P1, AP000457.1, RNU6-113P, LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3, BTG3-AS1, AP000432.1.
- chr21:19,893,113–21,975,681, 17 genes, copy number 8–11: LINC01683, LINC02573, RNU6-772P, RN7SKP147, FDPSP6, KRT18P2, RPS3AP1, AP001506.1, LINC00320, PPIAP1, NCAM2, AP001136.1, AP001117.1, AF241725.1, LINC00317, LINC01425, AP000472.1.
- chr21:44,217,014–46,691,226, 117 genes, copy number 5–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 19,907. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
